Somatic mutation profile of tumor specimen TCGA-33-AASB-01A (aliquot TCGA-33-AASB-01A-11D-A401-08) from TCGA case TCGA-33-AASB, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 66.2 years (24,183 days).
Specimen TCGA-33-AASB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3957fa7-1dc0-4d3a-b2c1-6daf9952d0e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-33-AASB-11A (Solid Tissue Normal), aliquot TCGA-33-AASB-11A-11D-A401-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bdc073ab-ed13-4535-a715-1d32d3c952c1

The open-access MAF lists 411 somatic variants for this specimen: 328 protein-altering or splice-affecting, 79 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 279, Silent 79, Nonsense Mutation 20, Frame Shift Del 11, Splice Site 10, Frame Shift Ins 5, RNA 2, Splice Region 2, Intron 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL3A1 | c.2337+1G>A p.X779_splice | Splice Site (SNP) | VAF 14/71 reads (20%) | catalogued as rs587779663, CS971686, COSV100482417; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KEAP1 | c.959G>T p.R320L | Missense Mutation (SNP) | VAF 20/37 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs1239985410, COSV50260372, COSV50272556, COSV50274400; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 27/58 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.2026G>T p.A676S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1369483651, COSV99445769; called by muse, mutect2, varscan2
- ABCA7 | c.608T>A p.L203H | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV99565114; called by muse, mutect2, varscan2
- ACAN | c.848C>A p.T283K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749047801, COSV100716994; called by muse, mutect2, varscan2
- ACAN | c.2158G>A p.A720T | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs1314113660, COSV100716996, COSV61362988; called by muse, mutect2, varscan2
- ACE | c.2317G>T p.V773L | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99326387; called by muse, mutect2
- ACSBG2 | c.654C>A p.S218R | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.595); catalogued as COSV99397166; called by muse, mutect2, varscan2
- ADAMTS10 | c.2660+2T>A p.X887_splice | Splice Site (SNP) | VAF 10/20 reads (50%) | catalogued as COSV99546443; called by muse, mutect2, varscan2
- ADAMTS3 | c.2749T>A p.C917S | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV54397633; called by muse, mutect2, varscan2
- ADGRB3 | c.2288G>T p.G763V | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100999697; called by muse, mutect2
- ADGRG7 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99840493; called by muse, mutect2, varscan2
- ADGRV1 | c.3871G>T p.E1291* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as COSV101315471; called by muse, mutect2, varscan2
- AFP | c.650G>T p.S217I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99889683; called by muse, mutect2, varscan2
- AGBL2 | c.559G>T p.V187F | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100101242, COSV54092550; called by muse, mutect2, varscan2
- AGL | c.3207G>T p.R1069S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.777); catalogued as COSV99648425; called by muse, mutect2, varscan2
- AGMO | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as COSV100693564; called by muse, mutect2, varscan2
- AKAP9 | c.4374A>T p.Q1458H | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV100661886; called by muse, mutect2, varscan2
- ALDH8A1 | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); catalogued as COSV55640284, COSV55641714; called by muse, mutect2, varscan2
- ALMS1 | c.8518G>T p.D2840Y | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1157236247, COSV100041083; called by muse, mutect2, varscan2
- ALMS1 | c.11950G>T p.G3984C | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52516201; called by muse, mutect2, varscan2
- ALMS1 | c.11951G>T p.G3984V | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); catalogued as rs745830774, COSV100041087; called by muse, mutect2, varscan2
- ANXA9 | c.178G>T p.D60Y | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs998784689, COSV100929056; called by muse, mutect2
- AOPEP | c.1770C>A p.Y590* (on ENST00000375315 / NM_001193329.1; = p.Y491* on NM_032823.5) | Nonsense Mutation (SNP) | VAF 13/85 reads (15%) | catalogued as COSV99948667; called by muse, mutect2, varscan2
- APOBEC3G | c.437G>T p.R146L | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.403); catalogued as COSV68470214; called by muse, mutect2, varscan2
- ASPRV1 | c.116G>T p.C39F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.06); catalogued as COSV100208392; called by muse, mutect2
- ASTN2 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.027); catalogued as rs929394684, COSV100524624; called by muse, mutect2, varscan2
- ASXL3 | c.1819T>A p.C607S | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.09); catalogued as COSV99323323; called by muse, mutect2
- ATAD2 | c.1012G>T p.A338S | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV54877688, COSV99784021; called by muse, mutect2, varscan2
- ATP10D | c.644A>G p.E215G | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99905116; called by muse, mutect2, varscan2
- B4GALT6 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | catalogued as COSV52702410; called by muse, mutect2, varscan2
- BEND2 | c.2356G>T p.E786* | Nonsense Mutation (SNP) | VAF 35/90 reads (39%) | catalogued as COSV66221727; called by muse, mutect2, varscan2
- BEND2 | c.2355G>T p.Q785H | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.781); catalogued as COSV101192574; called by muse, mutect2, varscan2
- BEND4 | c.673A>T p.T225S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.009); catalogued as COSV101549710; called by muse, mutect2, varscan2
- BOD1L1 | c.3614A>T p.K1205M | Missense Mutation (SNP) | VAF 92/190 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV50014729, COSV99238336; called by muse, mutect2, varscan2
- BPIFB2 | c.1080G>T p.V360= | Splice Region (SNP) | VAF 7/16 reads (44%) | catalogued as rs1432471586, COSV99401124; called by muse, mutect2, varscan2
- C6 | c.2362T>C p.S788P | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV99666485; called by muse, mutect2, varscan2
- CACNA1C | c.4102G>T p.V1368L | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.973); catalogued as rs1234874360, COSV59697392; called by muse, mutect2, varscan2
- CACNA1H | c.6487G>T p.G2163W | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as rs370724421, COSV99326326; called by muse, mutect2, varscan2
- CALCRL | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.075); catalogued as COSV101130878; called by muse, mutect2
- CALR3 | c.569C>A p.S190* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as COSV99522049; called by muse, mutect2, varscan2
- CCDC102B | c.267A>T p.E89D | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100102113; called by muse, mutect2, varscan2
- CCDC27 | c.74C>A p.S25Y | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.278); catalogued as COSV99622065; called by muse, mutect2, varscan2
- CCDC88B | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); catalogued as COSV100104991; called by muse, mutect2, varscan2
- CCZ1 | c.438+1G>A p.X146_splice | Splice Site (SNP) | VAF 19/50 reads (38%) | catalogued as COSV100382684; called by muse, mutect2, varscan2
- CD1E | c.200G>T p.W67L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV100936908; called by muse, mutect2, varscan2
- CDH10 | c.2121C>A p.N707K | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.783); catalogued as rs1293883738, COSV100050896, COSV52584655; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3875A>G p.Y1292C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100575062; called by muse, mutect2, varscan2
- CEACAM20 | c.1148C>A p.A383D | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100386773; called by muse, mutect2, varscan2
- CELSR1 | c.5660G>T p.C1887F | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1429326836, COSV99416725, COSV99418713; called by muse, mutect2, varscan2
- CELSR3 | c.1085A>G p.Y362C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99372493; called by muse, mutect2, varscan2
- CENPF | c.6158A>G p.E2053G | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV100871482; called by muse, mutect2, varscan2
- CEP128 | c.2698C>A p.Q900K | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as COSV99823604; called by muse, mutect2, varscan2
- CEP44 | c.329G>T p.C110F | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1349064778, COSV99639187; called by muse, mutect2, varscan2
- CFAP46 | c.6617C>A p.S2206Y | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.77); PolyPhen benign (0.009); catalogued as rs768731240, COSV99583890; called by muse, mutect2, varscan2
- CFAP69 | c.487A>T p.I163F | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100289756; called by muse, mutect2, varscan2
- CFH | c.672G>T p.K224N | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); catalogued as COSV100661287, COSV100661613; called by muse, mutect2, varscan2
- CLDN22 | c.11T>C p.V4A | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as COSV100032779; called by muse, mutect2, varscan2
- CNKSR2 | c.938G>T p.W313L | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV99667291; called by muse, mutect2, varscan2
- CNTN3 | c.1121C>G p.S374* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99723213; called by muse, mutect2, varscan2
- CNTN4 | c.2089G>T p.A697S | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.222); catalogued as COSV100638815; called by muse, mutect2, varscan2
- COG6 | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs752065178, COSV100742573, COSV62996383; called by muse, mutect2, varscan2
- COL11A1 | c.862C>A p.P288T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as rs748315186, COSV100615029; called by muse, mutect2, varscan2
- COL23A1 | c.712G>A p.G238R | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1310972079, COSV101178039; called by muse, mutect2, varscan2
- COL3A1 | c.3911G>A p.S1304N | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs61735537, COSV100482421; called by muse, mutect2, varscan2
- COLEC12 | c.1543G>T p.G515W | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101231952; called by muse, mutect2
- COPA | c.3490A>T p.N1164Y | Missense Mutation (SNP) | VAF 78/195 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99614556; called by muse, mutect2, varscan2
- CPED1 | c.2830G>T p.E944* | Nonsense Mutation (SNP) | VAF 11/92 reads (12%) | catalogued as COSV100119950; called by muse, mutect2, varscan2
- CRACR2A | c.1159A>G p.R387G | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV99364549; called by muse, mutect2, varscan2
- CRTC1 | c.1897C>T p.R633C | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766452972, COSV100119023; called by muse, mutect2, varscan2
- CSF2RA | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV100817431; called by muse, mutect2, varscan2
- CSMD2 | c.6847G>A p.A2283T | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.327); catalogued as rs370698179, COSV99585798; called by muse, mutect2, varscan2
- CTNNA2 | c.2648C>G p.S883C (on ENST00000402739 / NM_001282597.3; = p.S835C on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV100559435; called by muse, mutect2, varscan2
- CTNNA3 | c.1372C>A p.Q458K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV101045832; called by muse, mutect2, varscan2
- CYP2B6 | c.685G>T p.G229W | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100137284; called by muse, mutect2, varscan2
- DBX2 | c.586G>T p.D196Y | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100224172; called by muse, mutect2, varscan2
- DCN | c.860G>C p.G287A | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV50006030, COSV50008234, COSV99271780; called by muse, mutect2, varscan2
- DENND2A | c.675G>T p.R225S | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99325516; called by muse, mutect2, varscan2
- DICER1 | c.2590G>A p.A864T | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.718); catalogued as COSV100601752, COSV58630963; called by muse, mutect2, varscan2
- DIO2 | c.728G>T p.G243V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV101375816, COSV70445331; called by muse, mutect2, varscan2
- DNAH11 | c.5460+6T>C | Splice Region (SNP) | VAF 10/63 reads (16%) | catalogued as COSV100176952; called by muse, mutect2, varscan2
- DNAH5 | c.3035C>A p.A1012E | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as COSV99444742; called by muse, mutect2, varscan2
- DNAH9 | c.7441G>A p.G2481S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52377307; called by muse, mutect2, varscan2
- DNER | c.1794C>A p.D598E | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100518292; called by muse, mutect2, varscan2
- DOCK4 | c.5569T>C p.C1857R | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.085); catalogued as COSV101447770; called by muse, mutect2, varscan2
- DPF2 | c.155A>G p.N52S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs763960510, COSV52889198, COSV99361323; called by muse, mutect2, varscan2
- DPY19L2 | c.1715G>T p.C572F | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100192736; called by muse, mutect2, varscan2
- DUS3L | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144091319, COSV100287770; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1944G>C p.E648D (on ENST00000361735 / NM_015935.5; = p.E562D on NM_014955.3) | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV100675725, COSV100675763; called by muse, mutect2, varscan2
- EP300 | c.3667C>T p.Q1223* | Nonsense Mutation (SNP) | VAF 25/36 reads (69%) | catalogued as COSV54331877, COSV54336120; called by muse, mutect2, varscan2
- EPHA3 | c.934C>G p.R312G | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100342698, COSV60696147; called by muse, mutect2, varscan2
- EPHA5 | c.758C>A p.S253Y | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV56679851, COSV99896039; called by muse, mutect2, varscan2
- EPHA6 | c.1610C>A p.P537H | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs772449969, COSV101060811; called by muse, varscan2
- FAM71F2 | c.310G>C p.G104R | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); catalogued as COSV101100653, COSV101100726; called by muse, mutect2, varscan2
- FCHO1 | c.943G>T p.G315W | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs1312483947, COSV99405799; called by muse, mutect2, varscan2
- FCHO1 | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs1338790902, COSV99405800; called by muse, mutect2, varscan2
- FLG | c.10624G>T p.D3542Y | Missense Mutation (SNP) | VAF 78/292 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100910485; called by muse, varscan2
- FLNC | c.5911G>T p.E1971* | Nonsense Mutation (SNP) | VAF 10/78 reads (13%) | catalogued as rs1306584705, COSV100367613, COSV57961107; called by muse, mutect2, varscan2
- FLOT1 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs752367378, COSV100899807; called by muse, mutect2, varscan2
- FMO1 | c.809G>C p.G270A | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100707687; called by muse, mutect2, varscan2
- FOXF2 | c.569G>T p.R190L | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs1455309506, COSV99452933; called by muse, mutect2, varscan2
- FRZB | c.758A>G p.E253G | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99717261; called by muse, mutect2, varscan2
- FSHR | c.138G>T p.R46S | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as COSV100436532; called by muse, mutect2, varscan2
- GALNT6 | c.1401G>T p.Q467H | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as COSV100695290; called by muse, mutect2, varscan2
- GLRA1 | c.628C>A p.L210I | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV99199414; called by muse, mutect2, varscan2
- GLYATL1 | c.187-1G>A p.X63_splice (on ENST00000317391 / NM_001354699.1; = p.X94_splice on NM_080661.4) | Splice Site (SNP) | VAF 16/56 reads (29%) | catalogued as COSV100265131; called by muse, mutect2, varscan2
- GPRIN3 | c.1836G>T p.M612I | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100310576, COSV100310731; called by muse, mutect2, varscan2
- GRID1 | c.1485G>T p.Q495H | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.482); catalogued as COSV100021801; called by muse, mutect2, varscan2
- GRIN3A | c.1309C>A p.L437I | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV100701360; called by muse, mutect2, varscan2
- H1-2 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs61742489, COSV100642237; called by muse, mutect2, varscan2
- H2AC12 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.066); catalogued as COSV63616825; called by muse, mutect2, varscan2
- HASPIN | c.1132G>C p.V378L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV53992651, COSV99560323; called by muse, mutect2, varscan2
- HECTD4 | c.2305G>T p.V769F | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100295797; called by muse, mutect2, varscan2
- HS3ST4 | c.986G>T p.S329I | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100500003; called by muse, mutect2, varscan2
- HS6ST3 | c.1147C>T p.R383W | Missense Mutation (SNP) | VAF 83/122 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774158340, COSV65018227; called by muse, mutect2, varscan2
- IDO1 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.121); catalogued as COSV99503150; called by muse, mutect2, varscan2
- IFNG | c.70C>A p.Q24K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.405); catalogued as rs1284139476; called by muse, mutect2
- IFNG | c.69C>A p.C23* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as rs1325493656, COSV99971240; called by muse, mutect2
- IGHV3-43 | c.94C>A p.Q32K | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.031); catalogued as rs1171895308; called by muse, mutect2, varscan2
- IL5RA | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.556); catalogued as COSV99842648; called by muse, mutect2, varscan2
- IL9R | c.29-1G>A p.X10_splice | Splice Site (SNP) | VAF 10/49 reads (20%) | catalogued as COSV99729201; called by muse, mutect2, varscan2
- ILDR2 | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs1391408798, COSV99613175; called by muse, mutect2, varscan2
- ITGA10 | c.1012A>T p.T338S | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV100994690; called by muse, mutect2, varscan2
- ITGA2 | c.418G>T p.G140W | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99670184; called by muse, mutect2, varscan2
- ITGA2 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV99670186; called by muse, mutect2, varscan2
- KCNH5 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV100525279; called by muse, mutect2, varscan2
- KCNK1 | c.835A>T p.M279L | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100785661; called by muse, mutect2, varscan2
- KCNQ5 | c.542C>A p.S181Y | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59648044, COSV59671953; called by muse, mutect2, varscan2
- KDM5B | c.1904A>T p.K635M | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99350009; called by muse, mutect2, varscan2
- KDR | c.2178A>T p.R726S | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1195403759, COSV99816681; called by muse, mutect2, varscan2
- KIF19 | c.1072T>A p.S358T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV100738926; called by mutect2, varscan2
- KIF1C | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100296948; called by muse, mutect2, varscan2
- KIF2A | c.1771G>T p.D591Y | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101136235; called by muse, mutect2, varscan2
- KIF3C | c.1061C>G p.S354C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV99267023; called by muse, mutect2, varscan2
- KLHL11 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as rs782604640, COSV100044165; called by muse, mutect2, varscan2
- KPNA6 | c.10A>G p.M4V | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs147022148; called by muse, mutect2, varscan2
- KRT31 | c.399C>A p.N133K | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52435279, COSV99289372; called by muse, mutect2, varscan2
- KRT37 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.03); catalogued as COSV99845258; called by muse, mutect2, varscan2
- KRTAP10-4 | c.141C>A p.C47* | Nonsense Mutation (SNP) | VAF 11/109 reads (10%) | catalogued as COSV100551832, COSV100554070; called by muse, varscan2
- LAMA2 | c.6460T>A p.C2154S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101369979, COSV70345761; called by muse, mutect2, varscan2
- LAMB4 | c.2531G>T p.G844V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99222662; called by muse, mutect2, varscan2
- LARP1B | c.1934C>T p.P645L | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99217761; called by muse, mutect2, varscan2
- LATS1 | c.1879A>T p.R627W | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV53589205; called by muse, mutect2, varscan2
- LDAH | c.125G>T p.R42M | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.351); catalogued as COSV52974027; called by muse, mutect2, varscan2
- LGR6 | c.1382C>A p.S461Y (on ENST00000367278 / NM_001017403.1; = p.S409Y on NM_021636.3) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as COSV99706000; called by muse, mutect2, varscan2
- LMAN1 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755799692, COSV51826827, COSV99195313; called by muse, mutect2, varscan2
- LONRF1 | c.2290C>G p.L764V | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101238172; called by muse, mutect2, varscan2
- LRP5 | c.3904C>A p.Q1302K | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV99591379; called by muse, mutect2
- LRRC74A | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs745363240; called by muse, mutect2, varscan2
- LRRTM4 | c.162T>A p.D54E | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.101); catalogued as COSV101297419; called by muse, mutect2, varscan2
- LSAMP | c.105C>A p.N35K | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV100369072, COSV61295180; called by muse, mutect2, varscan2
- LY75-CD302 | c.5497C>A p.L1833M | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV99373494; called by muse, mutect2
- MAGEB10 | c.625G>T p.G209C | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.896); catalogued as COSV100775125; called by muse, mutect2, varscan2
- MAGEC3 | c.655A>C p.T219P | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV100024805, COSV100025747; called by muse, mutect2, varscan2
- MED4 | c.808G>C p.D270H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99319848; called by muse, mutect2, varscan2
- MINDY3 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV99510452, COSV99510725; called by muse, mutect2, varscan2
- MKRN3 | c.1319C>G p.A440G | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.037); catalogued as COSV100090686; called by muse, mutect2, varscan2
- MLH1 | c.171G>C p.K57N | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51616827, COSV99212318; called by muse, mutect2, varscan2
- MMUT | c.1260A>T p.K420N | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.127); catalogued as COSV99222150; called by muse, mutect2, varscan2
- MPP7 | c.1525G>T p.D509Y | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV100516879; called by muse, mutect2, varscan2
- MS4A7 | c.65C>G p.P22R | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.289); catalogued as COSV100279339, COSV55731903; called by muse, mutect2, varscan2
- MUC17 | c.2474C>A p.T825N | Missense Mutation (SNP) | VAF 41/242 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV60297063; called by muse, mutect2, varscan2
- MYH15 | c.2646G>T p.R882S | Missense Mutation (SNP) | VAF 66/116 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV99842199; called by muse, mutect2, varscan2
- MYH4 | c.742G>T p.G248C | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99700032; called by muse, mutect2, varscan2
- NAT1 | c.35A>G p.Y12C | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100306431; called by muse, mutect2, varscan2
- NGB | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as COSV99836167; called by muse, mutect2
- NIBAN1 | c.2078A>T p.E693V | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV100836200; called by muse, mutect2, varscan2
- NLRP12 | c.1849T>A p.L617M | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100144814, COSV60746426; called by muse, mutect2, varscan2
- NLRP4 | c.2138C>A p.S713Y | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as COSV100015572; called by muse, mutect2, varscan2
- NOP58 | c.1072-1G>T p.X358_splice | Splice Site (SNP) | VAF 8/104 reads (8%) | catalogued as COSV99970429; called by muse, mutect2
- NPSR1 | c.566C>A p.T189K | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100705708; called by muse, mutect2, varscan2
- NTNG2 | c.387G>T p.K129N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1162547670, COSV100647235, COSV100647338; called by muse, mutect2, varscan2
- NUP153 | c.3382A>G p.K1128E | Missense Mutation (SNP) | VAF 58/92 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs750489930, COSV100019760; called by muse, mutect2, varscan2
- NUP210 | c.4099G>T p.V1367F | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV99595545; called by muse, mutect2, varscan2
- NUTM1 | c.1063C>A p.P355T | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.558); catalogued as COSV100148819; called by muse, mutect2, varscan2
- NUTM1 | c.1064C>A p.P355H | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.919); catalogued as COSV100148820; called by muse, mutect2, varscan2
- OBSL1 | c.4138_4139insT p.R1380Lfs*3 | Frame Shift Ins (INS) | VAF 9/28 reads (32%) | catalogued as COSV99522622; called by mutect2, pindel, varscan2
- OR10T2 | c.176C>G p.P59R | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100554803; called by muse, mutect2, varscan2
- OR2AG2 | c.610G>T p.V204L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV100643066; called by muse, mutect2
- OR2L2 | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | catalogued as rs546778867, COSV63547603; called by muse, mutect2, varscan2
- OR4D6 | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100271562; called by muse, mutect2, varscan2
- OR4N2 | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100269369; called by muse, mutect2, varscan2
- OR4P4 | c.337C>A p.L113I | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.45); catalogued as COSV100111546; called by muse, mutect2, varscan2
- OR51G2 | c.5C>T p.T2I | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as COSV100432039; called by muse, mutect2, varscan2
- OR52K2 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV100355622; called by muse, mutect2, varscan2
- OR5AN1 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100004283, COSV58322865; called by muse, mutect2, varscan2
- OR5D13 | c.289T>G p.S97A | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV100686705; called by muse, mutect2, varscan2
- OR5J2 | c.858C>G p.N286K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV100398894; called by muse, mutect2, varscan2
- OR6Q1 | c.222G>T p.W74C | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100109334; called by muse, mutect2, varscan2
- OR7D4 | c.806A>T p.Q269L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV100432590; called by muse, mutect2, varscan2
- OR8S1 | c.529T>A p.Y177N | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100043448; called by muse, mutect2, varscan2
- OR9K2 | c.1004T>A p.L335H (on ENST00000305377; = p.L313H on NM_001005243.1) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.733); catalogued as COSV100543733; called by muse, mutect2, varscan2
- OSBPL3 | c.1986G>T p.M662I | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as COSV100513668; called by muse, mutect2, varscan2
- OXR1 | c.1462C>G p.Q488E (on ENST00000442977 / NM_001198532.1; = p.Q487E on NM_018002.3) | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs934936995, COSV100366695; called by muse, mutect2
- PAIP1 | c.545A>C p.Q182P | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV100166489; called by muse, mutect2, varscan2
- PAPPA | c.1712A>G p.Y571C | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100072821; called by muse, mutect2
- PAPPA2 | c.1638G>T p.Q546H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs772369374, COSV100866533; called by muse, mutect2, varscan2
- PARP14 | c.2915A>C p.E972A | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV101506222; called by muse, mutect2, varscan2
- PASD1 | c.258A>T p.K86N | Missense Mutation (SNP) | VAF 41/60 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100949067; called by muse, mutect2, varscan2
- PCDH15 | c.5789C>T p.S1930F | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.07); catalogued as COSV100214970, COSV100221507; called by muse, mutect2, varscan2
- PCDH18 | c.2584C>T p.L862F | Missense Mutation (SNP) | VAF 71/174 reads (41%) | SIFT tolerated (1); PolyPhen probably damaging (0.916); catalogued as COSV100787021; called by muse, mutect2, varscan2
- PCDHA8 | c.2074G>T p.A692S | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.006); catalogued as COSV100969010; called by muse, mutect2, varscan2
- PCDHGA1 | c.844C>T p.H282Y | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV65300605; called by muse, mutect2, varscan2
- PDE1C | c.965C>G p.S322* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as COSV100370813; called by muse, mutect2, varscan2
- PDZD2 | c.188C>A p.P63H | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV56875812; called by muse, mutect2, varscan2
- PEG3 | c.143G>A p.R48K | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV99687192; called by muse, mutect2, varscan2
- PGBD1 | c.435G>T p.M145I | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV52556578, COSV99459681; called by muse, mutect2, varscan2
- PIGB | c.529dup p.C177Lfs*79 | Frame Shift Ins (INS) | VAF 18/103 reads (17%) | catalogued as rs1356026422; called by mutect2, varscan2
- PM20D2 | c.529G>T p.G177W | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99248174; called by muse, mutect2, varscan2
- PNLIP | c.1155G>T p.Q385H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100981620; called by muse, mutect2, varscan2
- POTEH | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.364); catalogued as COSV100624662; called by muse, varscan2
- PPHLN1 | c.1350G>T p.K450N | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as COSV99871446; called by muse, mutect2, varscan2
- PSEN1 | c.676C>G p.L226V | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as CM066192, COSV99997575; called by muse, mutect2, varscan2
- PTGS1 | c.731G>T p.R244L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99792893; called by muse, mutect2, varscan2
- PTPN2 | c.127A>T p.R43* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as COSV100518324; called by muse, mutect2, varscan2
- PTPRB | c.977A>T p.H326L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.102); catalogued as COSV99715676; called by muse, mutect2, varscan2
- PTPRZ1 | c.6147G>C p.R2049S | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV101099481; called by muse, mutect2, varscan2
- PXDNL | c.2038C>A p.L680I | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.749); catalogued as rs1448517559, COSV100681220; called by muse, mutect2, varscan2
- PYGL | c.2033G>T p.G678V | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99368244; called by muse, mutect2, varscan2
- R3HDM1 | c.70A>G p.K24E | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.75); PolyPhen benign (0.049); catalogued as COSV99925655; called by muse, mutect2, varscan2
- RAD9B | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100799258; called by muse, mutect2, varscan2
- RBM46 | c.1420A>G p.S474G | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV99907861; called by muse, mutect2, varscan2
- RGS7 | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 21/55 reads (38%) | catalogued as COSV100464460; called by muse, mutect2, varscan2
- RIMS1 | c.1831G>T p.D611Y | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV99323927; called by muse, mutect2, varscan2
- RIMS2 | c.3659G>A p.G1220E | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (1); catalogued as COSV99158744; called by muse, mutect2, varscan2
- RNF128 | c.125A>G p.N42S | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.312); catalogued as COSV100175966; called by muse, mutect2, varscan2
- RNF168 | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.06); catalogued as COSV100534827; called by muse, mutect2, varscan2
- ROR2 | c.2324C>A p.T775N | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV100995474; called by muse, mutect2
- RPH3A | c.485C>A p.P162H (on ENST00000389385 / NM_001143854.2; = p.P158H on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101231768, COSV66990753; called by muse, mutect2, varscan2
- RYR3 | c.7776T>A p.D2592E (on ENST00000389232; = p.D2593E on NM_001036.6) | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV101211963; called by muse, mutect2, varscan2
- SCN5A | c.2122C>A p.Q708K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100346442; called by muse, mutect2, varscan2
- SCN7A | c.4147A>C p.I1383L | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as COSV101313080; called by muse, mutect2, varscan2
- SCN8A | c.2531G>A p.R844Q | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1476532344, COSV61979158; called by muse, mutect2, varscan2
- SEC23IP | c.2369G>T p.G790V | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767430384, COSV100956739; called by muse, mutect2, varscan2
- SEL1L | c.478A>G p.K160E | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.01); catalogued as COSV100377642; called by muse, mutect2, varscan2
- SEMA3E | c.2070G>T p.R690S | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100317237, COSV57083392; called by muse, mutect2, varscan2
- SEMA5A | c.1991G>T p.R664L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs199952121, COSV101227030, COSV66791912; called by muse, mutect2, varscan2
- SERPINI1 | c.762G>T p.M254I | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV55513185; called by muse, mutect2, varscan2
- SETDB1 | c.664C>A p.Q222K | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV99643722; called by muse, mutect2, varscan2
- SH2B1 | c.1546G>T p.G516C | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100450831; called by muse, mutect2, varscan2
- SLC14A1 | c.827C>A p.A276D | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV100424797; called by muse, mutect2
- SLC25A45 | c.265C>T p.H89Y | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0.007); catalogued as rs745954311, COSV99587221; called by muse, mutect2, varscan2
- SLC39A12 | c.217G>T p.G73W | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV101069830; called by muse, mutect2, varscan2
- SLC44A5 | c.2145G>T p.Q715H | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.289); catalogued as COSV100901084; called by muse, mutect2, varscan2
- SLC44A5 | c.1550C>T p.A517V | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100901085; called by muse, mutect2, varscan2
- SLC51A | c.161C>A p.T54N | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs765786336, COSV99580020; called by muse, mutect2, varscan2
- SLITRK3 | c.736T>A p.W246R | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99578482; called by muse, mutect2, varscan2
- SORCS1 | c.2355C>A p.Y785* | Nonsense Mutation (SNP) | VAF 25/57 reads (44%) | catalogued as COSV99543136; called by muse, mutect2, varscan2
- SPEF2 | c.4738-1G>T p.X1580_splice | Splice Site (SNP) | VAF 16/76 reads (21%) | catalogued as COSV100288660; called by muse, mutect2, varscan2
- SPHKAP | c.224A>G p.D75G | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100763676; called by muse, mutect2, varscan2
- SPRR3 | c.348G>T p.K116N | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.1); catalogued as COSV99768402; called by muse, mutect2, varscan2
- SPRY3 | c.675G>A p.M225I | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as rs1180278920, COSV57144129; called by muse, mutect2, varscan2
- ST8SIA3 | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 21/67 reads (31%) | PolyPhen probably damaging (1); catalogued as COSV100129286; called by muse, mutect2, varscan2
- STAB1 | c.2380C>A p.R794S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100401187; called by muse, mutect2, varscan2
- STK11IP | c.119A>T p.Q40L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.384); catalogued as COSV99822174; called by muse, mutect2, varscan2
- SULT1B1 | c.681C>A p.H227Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as COSV100150092; called by muse, mutect2, varscan2
- SYNJ1 | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59147504; called by muse, mutect2, varscan2
- TAAR8 | c.523G>T p.G175W | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV51586051, COSV99257050; called by muse, varscan2
- TAAR8 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); catalogued as COSV99257102; called by muse, varscan2
- TAF4 | c.1401G>A p.M467I | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV99433436; called by muse, mutect2, varscan2
- TAGAP | c.1631G>A p.R544K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100487259; called by muse, mutect2, varscan2
- TAGAP | c.1270G>C p.E424Q | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV100487260; called by muse, mutect2, varscan2
- TAS2R38 | c.942G>T p.W314C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV101516335; called by muse, mutect2, varscan2
- TBXT | c.1162C>A p.H388N | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.09); catalogued as COSV51617805, COSV99752055; called by muse, mutect2, varscan2
- TCTN2 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV100315079; called by muse, mutect2
- TIAM1 | c.3061C>A p.P1021T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.388); catalogued as COSV99732690; called by muse, mutect2, varscan2
- TLR4 | c.532G>T p.E178* (on ENST00000355622 / NM_138554.5; = p.E138* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 20/96 reads (21%) | catalogued as COSV100790596, COSV62922477; called by muse, mutect2, varscan2
- TMEM266 | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.154); catalogued as COSV101189559, COSV66379201; called by muse, mutect2, varscan2
- TMEM38B | c.455-1G>T p.X152_splice | Splice Site (SNP) | VAF 8/49 reads (16%) | catalogued as COSV101016185; called by muse, mutect2, varscan2
- TMPRSS11B | c.707G>C p.W236S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100219224; called by muse, mutect2, varscan2
- TRABD2A | c.628del p.E210Kfs*7 | Frame Shift Del (DEL) | VAF 48/154 reads (31%) | catalogued as COSV59101739; called by mutect2, pindel, varscan2
- TRAPPC9 | c.874C>T p.L292F | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.478); catalogued as COSV101226634; called by muse, mutect2
- TRIM58 | c.490G>T p.V164L | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV63571423; called by muse, mutect2, varscan2
- TRIM58 | c.1193C>A p.P398Q | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100824865; called by muse, mutect2, varscan2
- TRIML2 | c.759G>T p.L253F | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV100455852; called by muse, mutect2, varscan2
- TRIO | c.1790G>C p.G597A | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100709808; called by muse, mutect2, varscan2
- TRPM6 | c.3998C>A p.P1333H | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV100665287; called by muse, mutect2
- TSPOAP1 | c.1222G>T p.G408C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as COSV99269991; called by muse, mutect2, varscan2
- TTC33 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100531791; called by muse, mutect2, varscan2
- TTLL13P | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV100296387; called by muse, mutect2, varscan2
- TTN | c.88723G>A p.D29575N (on ENST00000591111; = p.D22151N on NM_003319.4) | Missense Mutation (SNP) | VAF 22/54 reads (41%) | PolyPhen probably damaging (0.998); catalogued as rs1321355074, COSV100593468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBE2U | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370723679; called by muse, mutect2, varscan2
- UGT2B7 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as COSV100535100; called by muse, mutect2, varscan2
- UNC5D | c.2638C>T p.Q880* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99771969; called by muse, mutect2, varscan2
- UQCC1 | c.811G>C p.G271R | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100568279, COSV99051527; called by muse, mutect2, varscan2
- USH2A | c.14189C>A p.T4730N | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56358568; called by muse, mutect2, varscan2
- VIT | c.1091C>T p.T364I (on ENST00000389975 / NM_001177969.1; = p.T379I on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.16); catalogued as COSV101007116; called by muse, mutect2, varscan2
- WASHC4 | c.845G>C p.S282T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV100162030, COSV59890280; called by muse, mutect2, varscan2
- WDR7 | c.3872A>T p.Q1291L | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (1); PolyPhen probably damaging (0.932); catalogued as COSV99588460; called by muse, mutect2, varscan2
- WNT7A | c.854G>T p.G285V | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs913023174, COSV99540870; called by muse, mutect2, varscan2
- WNT7A | c.853G>T p.G285C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53201951, COSV99540872; called by muse, mutect2, varscan2
- XDH | c.3275A>G p.Y1092C | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.799); catalogued as COSV101051941; called by muse, mutect2, varscan2
- XIRP2 | c.3557C>A p.S1186Y (on ENST00000628543; = p.S1361Y on NM_152381.6) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV54693862; called by muse, mutect2, varscan2
- ZBBX | c.158G>A p.R53K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777704597, COSV100283064; called by muse, mutect2, varscan2
- ZBTB11 | c.1012G>T p.G338* | Nonsense Mutation (SNP) | VAF 7/75 reads (9%) | catalogued as COSV100465091; called by muse, mutect2
- ZBTB38 | c.1430G>A p.R477K | Missense Mutation (SNP) | VAF 4/89 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100375255, COSV58543526; called by muse, mutect2
- ZDBF2 | c.160C>G p.H54D | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100984331; called by muse, mutect2, varscan2
- ZFAND4 | c.805T>G p.L269V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV100762860; called by muse, mutect2, varscan2
- ZNF280A | c.1154A>T p.D385V | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV100130948; called by muse, mutect2, varscan2
- ZNF329 | c.932G>T p.G311V | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100798663; called by muse, mutect2, varscan2
- ZNF329 | c.931G>T p.G311W | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100798664; called by muse, mutect2, varscan2
- ZNF521 | c.1685G>T p.C562F | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100831405; called by muse, mutect2, varscan2
- ZNF616 | c.1829G>T p.C610F | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100348072, COSV57510681; called by muse, mutect2, varscan2
- ZNF778 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 67/118 reads (57%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100124261; called by muse, mutect2, varscan2
- ZSCAN22 | c.977G>T p.C326F | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100308253; called by muse, mutect2, varscan2
- ZSWIM2 | c.1334C>A p.P445H | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV99719903; called by muse, mutect2, varscan2
- AGFG2 | c.357_363dup p.V122Ifs*21 | Frame Shift Ins (INS) | VAF 18/104 reads (17%) | called by mutect2, varscan2
- BCHE | c.1498del p.A500Qfs*30 | Frame Shift Del (DEL) | VAF 28/91 reads (31%) | called by mutect2, pindel, varscan2
- CHRFAM7A | c.523+1del p.X175_splice | Splice Site (DEL) | VAF 15/52 reads (29%) | called by mutect2, pindel, varscan2
- COL22A1 | c.2357del p.G786Efs*29 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- COPS8 | c.274del p.T92Pfs*50 | Frame Shift Del (DEL) | VAF 21/68 reads (31%) | called by mutect2, pindel, varscan2
- EED | c.163dup p.T55Nfs*33 | Frame Shift Ins (INS) | VAF 20/66 reads (30%) | called by mutect2, pindel, varscan2
- FBXL7 | c.662del p.G221Afs*31 | Frame Shift Del (DEL) | VAF 14/66 reads (21%) | called by mutect2, pindel, varscan2
- GRB10 | c.1687_1695del p.K563_S565del (on ENST00000398812; = p.K517_S519del on NM_001001549.3) | In Frame Del (DEL) | VAF 12/76 reads (16%) | called by mutect2, pindel, varscan2
- IGHM | c.372C>A p.F124L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.72); called by mutect2, varscan2
- NYAP1 | c.1714del p.V572Cfs*2 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- OR2L2 | c.212dup p.N71Kfs*13 | Frame Shift Ins (INS) | VAF 93/198 reads (47%) | called by mutect2, pindel, varscan2
- RAB20 | c.79del p.E27Sfs*17 | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | called by mutect2, pindel, varscan2
- SSU72P8 | c.367C>A p.L123M | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- TCFL5 | c.1438del p.D480Tfs*4 | Frame Shift Del (DEL) | VAF 17/114 reads (15%) | called by mutect2, pindel, varscan2
- TNNI3K | c.2249_2258del p.V750Efs*11 | Frame Shift Del (DEL) | VAF 34/109 reads (31%) | called by mutect2, pindel, varscan2
- TPH2 | c.773del p.P258Lfs*10 | Frame Shift Del (DEL) | VAF 68/258 reads (26%) | called by mutect2, pindel, varscan2
- TPTE | c.622C>G p.L208V (on ENST00000618007 / NM_199261.4; = p.L190V on NM_199259.4) | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- XIRP2 | c.9554del p.T3185Kfs*19 (on ENST00000628543; = p.T3360Kfs*19 on NM_152381.6) | Frame Shift Del (DEL) | VAF 13/83 reads (16%) | called by mutect2, pindel, varscan2
- YTHDF2 | c.133-1_133del p.X45_splice | Splice Site (DEL) | VAF 28/79 reads (35%) | called by mutect2, pindel, varscan2
- ZNF26 | c.1468G>T p.A490S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ZNF827 | c.2639T>G p.V880G | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- AL121899.2 | c.669T>A p.A223= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV101198375; called by muse, mutect2, varscan2
- ANK3 | c.10122C>A p.G3374= | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as COSV99778227; called by muse, mutect2, varscan2
- ATP6AP1 | c.246G>T p.L82= | Silent (SNP) | VAF 32/53 reads (60%) | catalogued as COSV100645169; called by muse, mutect2, varscan2
- ATP8B4 | c.2112T>C p.N704= | Silent (SNP) | VAF 30/56 reads (54%) | catalogued as COSV99463568; called by muse, mutect2, varscan2
- BCL9L | c.345G>T p.R115= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV100599515; called by muse, mutect2, varscan2
- BOP1 | c.423G>A p.L141= | Silent (SNP) | VAF 15/66 reads (23%) | called by muse, mutect2, varscan2
- C1QTNF2 | c.486C>A p.P162= (on ENST00000393975; = p.P117= on NM_031908.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/81 reads (43%) | catalogued as rs147132918, COSV101220813; called by muse, mutect2, varscan2
- CDH12 | c.42G>C p.L14= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as rs899518674, COSV101201287, COSV66392947; called by muse, mutect2, varscan2
- CELF5 | c.309G>A p.Q103= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV99485651; called by muse, mutect2, varscan2
- CLRN2 | c.501A>G p.R167= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV101492681; called by mutect2, varscan2
- CNTNAP5 | c.3549C>A p.A1183= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1326133759, COSV101443026; called by muse, mutect2, varscan2
- COL12A1 | c.8355A>T p.P2785= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs1471668132, COSV100485378; called by muse, mutect2, varscan2
- CTNNA2 | c.1500G>T p.V500= | Silent (SNP) | VAF 2/24 reads (8%) | called by muse, mutect2
- DENND5B | c.3411T>C p.H1137= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV100170832; called by muse, mutect2, varscan2
- DOCK6 | c.1779C>T p.S593= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99370854; called by muse, mutect2, varscan2
- DPP10 | c.1690C>T p.L564= | Silent (SNP) | VAF 54/159 reads (34%) | catalogued as COSV100058462, COSV59685552; called by muse, mutect2, varscan2
- ECT2L | c.2694C>A p.I898= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV99238397; called by muse, mutect2, varscan2
- EIF2B2 | c.72G>A p.R24= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV99837612; called by muse, mutect2, varscan2
- EPB41L3 | c.2694G>T p.T898= | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as rs79015463, COSV100548132, COSV59442962; called by muse, mutect2, varscan2
- EWSR1 | c.1644T>G p.P548= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100130924; called by muse, mutect2, varscan2
- FCGR2A | c.849A>T p.T283= (on ENST00000271450 / NM_001136219.3; = p.T282= on NM_021642.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV99614945; called by muse, mutect2, varscan2
- FIG4 | c.1500G>A p.V500= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as COSV100019105; called by muse, mutect2, varscan2
- GCK | c.621G>T p.V207= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV100357010; called by muse, mutect2
- GON4L | c.2298C>T p.F766= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV99673244; called by muse, mutect2, varscan2
- IBSP | c.873A>C p.R291= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV99883380; called by muse, mutect2, varscan2
- IL18R1 | c.525C>T p.A175= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs199966642; called by muse, mutect2, varscan2
- IL7R | c.831C>A p.P277= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs766895607, COSV100285870, COSV57411013; called by muse, mutect2, varscan2
- INTS8 | c.528A>G p.Q176= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV100569116; called by muse, mutect2, varscan2
- KCND2 | c.831G>C p.L277= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV100473421; called by muse, mutect2, varscan2
- KCNJ10 | c.534C>G p.T178= | Silent (SNP) | VAF 44/106 reads (42%) | catalogued as COSV100927863; called by muse, mutect2, varscan2
- KCNT2 | c.3021T>C p.H1007= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as COSV99651400; called by muse, mutect2, varscan2
- KIRREL3 | c.1200T>A p.A400= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as COSV101375166; called by muse, mutect2, varscan2
- KLHL13 | c.582C>T p.D194= | Silent (SNP) | VAF 20/32 reads (63%) | catalogued as COSV99450958; called by muse, mutect2, varscan2
- KNDC1 | c.5052G>T p.A1684= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV100463267, COSV58846899; called by muse, mutect2, varscan2
- KRT6B | c.988C>T p.L330= | Silent (SNP) | VAF 28/146 reads (19%) | catalogued as rs1238611853, COSV99360406; called by muse, mutect2, varscan2
- LINGO2 | c.972C>A p.R324= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100430124; called by mutect2, varscan2
- LTK | c.1689C>T p.L563= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs373419915, COSV99540551; called by muse, mutect2, varscan2
- MEN1 | c.1575G>T p.G525= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV99580265; called by muse, mutect2, varscan2
- NFU1 | c.507T>G p.V169= (on ENST00000410022 / NM_001002755.4; = p.V145= on NM_015700.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as COSV100361043; called by muse, mutect2
- NPVF | c.258C>A p.A86= | Silent (SNP) | VAF 46/130 reads (35%) | catalogued as COSV99760148; called by muse, mutect2, varscan2
- OR10Z1 | c.306C>T p.F102= | Silent (SNP) | VAF 74/154 reads (48%) | catalogued as COSV100778936, COSV63524662; called by muse, mutect2, varscan2
- OR13F1 | c.288G>A p.G96= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV100594675; called by muse, mutect2, varscan2
- OR4D11 | c.387C>A p.P129= | Silent (SNP) | VAF 32/142 reads (23%) | catalogued as COSV100506455; called by muse, mutect2, varscan2
- OR8D1 | c.498G>T p.L166= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV100766526; called by muse, mutect2, varscan2
- P2RY8 | c.687G>A p.R229= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as rs747033091, COSV101183934; called by muse, mutect2, varscan2
- PCSK4 | c.993G>T p.V331= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs1436345946, COSV99278374; called by muse, mutect2, varscan2
- PEX6 | c.2892G>A p.E964= | Silent (SNP) | VAF 16/112 reads (14%) | catalogued as rs1561818538, COSV99769470; called by muse, mutect2, varscan2
- POU6F1 | c.1107G>T p.L369= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100374722; called by muse, mutect2
- PPP1R12A | c.2715G>T p.L905= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV99699952; called by muse, mutect2
- PRDX3 | c.222T>A p.G74= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as COSV100045288; called by muse, mutect2, varscan2
- PTPN7 | c.699G>T p.V233= (on ENST00000495688; = p.V272= on NM_002832.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as COSV100459632; called by muse, mutect2, varscan2
- PTPRN2 | c.2533C>T p.L845= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV101153264; called by muse, mutect2, varscan2
- PXDC1 | c.327G>T p.T109= | Silent (SNP) | VAF 89/147 reads (61%) | catalogued as rs755320106, COSV100977186, COSV66661728; called by muse, mutect2, varscan2
- R3HDM1 | c.69G>T p.V23= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV99925653; called by muse, mutect2, varscan2
- RIMBP2 | c.357G>T p.R119= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99898281; called by muse, mutect2, varscan2
- RP1L1 | c.3585C>A p.P1195= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV101222933; called by muse, mutect2, varscan2
- RPL7L1 | c.409C>T p.L137= | Silent (SNP) | VAF 12/161 reads (7%) | catalogued as COSV100491646; called by muse, mutect2
- SATB2 | c.1635G>T p.L545= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV53481855; called by muse, mutect2, varscan2
- SBK2 | c.963C>A p.I321= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs1299455826, COSV100705018; called by muse, mutect2, varscan2
- SCN5A | c.723G>T p.G241= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV100346446; called by muse, mutect2, varscan2
- SEMA6D | c.2352C>G p.T784= (on ENST00000316364 / NM_153618.2; = p.T722= on NM_020858.2) | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as rs374051234; called by muse, mutect2, varscan2
- SLC37A3 | c.1092G>T p.L364= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100405270; called by muse, mutect2, varscan2
- SPAG4 | c.1275C>T p.T425= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as COSV100958259; called by muse, mutect2, varscan2
- STC1 | c.493C>A p.R165= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as rs1330829565, COSV99282316; called by muse, mutect2, varscan2
- TJP1 | c.4104G>A p.E1368= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV100632290; called by muse, mutect2, varscan2
- TMCC3 | c.840A>G p.T280= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as rs1163763833, COSV99705190; called by muse, mutect2, varscan2
- TMEM139 | c.591C>A p.V197= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV100130839, COSV60081890; called by muse, mutect2, varscan2
- TMEM266 | c.177G>T p.T59= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as rs777571379, COSV101189558, COSV66379193; called by muse, mutect2, varscan2
- TRIM10 | c.1365C>A p.T455= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV100939603; called by muse, mutect2, varscan2
- TRIP6 | c.742C>T p.L248= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV99307420; called by muse, mutect2, varscan2
- TUT1 | c.1893G>T p.L631= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as COSV99544961; called by muse, mutect2
- UNC5D | c.1206T>G p.L402= | Silent (SNP) | VAF 65/185 reads (35%) | catalogued as COSV99771968; called by muse, mutect2, varscan2
- WDR91 | c.39G>T p.R13= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs1158844070, COSV100615545; called by muse, mutect2, varscan2
- WNT3 | c.612C>G p.L204= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99843043; called by muse, mutect2
- XDH | c.777G>T p.V259= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV101051942; called by muse, mutect2, varscan2
- XIRP2 | c.5754A>T p.L1918= (on ENST00000628543; = p.L2093= on NM_152381.6) | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99738274; called by muse, mutect2, varscan2
- ZIC4 | c.879G>A p.P293= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as COSV101267818; called by muse, mutect2, varscan2
- ZNF280A | c.639C>A p.I213= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as COSV100130949, COSV57480036; called by muse, mutect2, varscan2
- ZNF606 | c.726A>T p.T242= | Silent (SNP) | VAF 47/93 reads (51%) | catalogued as rs553016740, COSV100357108; called by muse, mutect2, varscan2
- MC3R | c.-12C>G | 5'UTR (SNP) | VAF 71/178 reads (40%) | catalogued as COSV99710420; called by muse, mutect2, varscan2
- MIR325 | n.12G>T | RNA (SNP) | VAF 43/76 reads (57%) | catalogued as rs72631830; called by muse, mutect2, varscan2
- OR2W5 | n.1158C>A | RNA (SNP) | VAF 21/94 reads (22%) | called by muse, mutect2, varscan2
- TNK2 | c.1452-132G>A | Intron (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100361002, COSV100361226; called by muse, mutect2
